Somatic mutation profile of tumor specimen BLGSP-71-06-00145-01A (aliquot BLGSP-71-06-00145-01A-01D-A663-33) from CGCI case BLGSP-71-06-00145, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt-like lymphoma; Tissue or organ of origin: Hematopoietic system, NOS.
Specimen BLGSP-71-06-00145-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Retroperitoneal; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41e07dc9-3ce5-452d-8939-fa6c95cb9f50.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-06-00145-12A (Buccal Cell Normal), aliquot BLGSP-71-06-00145-12A-01D-A663-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff848131-6d44-4815-a644-7028a00f63e1

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Nonsense Mutation 2, 5'UTR 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAI2 | c.155A>G p.Q52R | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV104382018; called by muse, mutect2, varscan2
- ID3 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV65800778; called by muse, varscan2
- MYC | c.169C>A p.P57T (on ENST00000377970; = p.P72T on NM_002467.6) | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52367722, COSV52368976, COSV52369330; called by muse, varscan2
- MYC | c.200C>T p.S67F (on ENST00000377970; = p.S82F on NM_002467.6) | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV52375491; called by muse, varscan2
- PCBP1 | c.879C>A p.C293* | Nonsense Mutation (SNP) | VAF 185/475 reads (39%) | catalogued as COSV57851245; called by muse, mutect2, varscan2
- DDX3X | c.762G>A p.K254= (on ENST00000399959; = p.K255= on NM_001356.5) | Splice Region (SNP) | VAF 152/168 reads (90%) | called by muse, mutect2, varscan2
- KMT2D | c.8768G>A p.G2923D | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.084); called by muse, mutect2
- BACH2 | c.-554C>T | 5'UTR (SNP) | VAF 8/14 reads (57%) | catalogued as rs1562549139, COSV57590552, COSV57590602; called by muse, mutect2, varscan2
- RUBCNL | c.-123+1269C>G | Intron (SNP) | VAF 30/530 reads (6%) | called by muse, mutect2
